Somatic mutation profile of tumor specimen SM-JU33G (aliquot 7316UP-2165) from CPTAC case C464694, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen SM-JU33G: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aca06842-e169-4388-b471-6509a1bc37d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105273 (Blood Derived Normal), aliquot 7316UP-1220-1105273; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eedd64a0-c546-4c80-a58b-9e0031658ae6

The open-access MAF lists 133 somatic variants for this specimen: 85 protein-altering or splice-affecting, 29 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 29, Frame Shift Del 9, Intron 7, Nonsense Mutation 6, RNA 5, 5'UTR 4, Frame Shift Ins 2, 5'Flank 2, 3'UTR 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 78/236 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 33/163 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 405/506 reads (80%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACOT9 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs771016382; called by muse, mutect2, varscan2
- ARAP3 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs747769367; called by muse, mutect2, varscan2
- B3GLCT | c.650T>G p.L217* | Nonsense Mutation (SNP) | VAF 19/88 reads (22%) | catalogued as rs1481842523; called by muse, mutect2, varscan2
- BAHCC1 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs537847945; called by muse, mutect2
- CCDC39 | c.2716G>C p.V906L | Missense Mutation (SNP) | VAF 58/351 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV99870139; called by muse, mutect2, varscan2
- COL1A2 | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 124/618 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs530026906, COSV51955410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.12049G>A p.V4017M | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1206121954, COSV54202849; called by muse, mutect2, varscan2
- DYNC2H1 | c.10772C>T p.T3591M | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.234); catalogued as rs370617490; called by muse, mutect2, varscan2
- EFR3B | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0.018); catalogued as rs926688402; called by muse, mutect2, varscan2
- FBXO34 | c.2054A>G p.N685S | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1566569899; called by muse, mutect2, varscan2
- FOXD4 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 150/845 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs781276183; called by muse, mutect2, varscan2
- FTMT | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.551); catalogued as rs1400684823, COSV58419742; called by muse, mutect2, varscan2
- GABRE | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs553890653, COSV64819053; called by muse, mutect2, varscan2
- GRM4 | c.2305G>A p.V769M | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs780548540; called by muse, mutect2, varscan2
- LARGE2 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 83/374 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs746500511; called by muse, mutect2, varscan2
- LEF1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1269291681; called by muse, mutect2, varscan2
- LHFPL1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs762194253, COSV64333341; called by muse, mutect2, varscan2
- MUC16 | c.5069G>T p.G1690V | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.301); catalogued as COSV101199304; called by muse, mutect2, varscan2
- NOBOX | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373431640; called by muse, mutect2
- PHKA2 | c.784A>G p.I262V | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1384160727; called by muse, mutect2, varscan2
- PNLIPRP1 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs114165255; called by mutect2, varscan2
- RUFY2 | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs996219946; called by muse, mutect2
- SLC22A7 | c.605G>A p.R202H (on ENST00000372585 / NM_153320.2; = p.R200H on NM_006672.3) | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs372008286; called by muse, mutect2, varscan2
- SLC4A1 | c.1910G>A p.G637D | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs769977105; called by muse, mutect2, varscan2
- UBQLNL | c.669G>T p.L223F | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs564556578, COSV66493216; called by muse, mutect2, varscan2
- ZBTB20 | c.638G>A p.R213Q (on ENST00000474710 / NM_001164342.2; = p.R140Q on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1195464738, COSV61851404; called by muse, mutect2, varscan2
- ABCA1 | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ABCA3 | c.5093C>G p.P1698R | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ALDH1L1 | c.2510G>A p.G837D | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKFY1 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ARHGAP31 | c.3499_3505del p.I1167Lfs*4 | Frame Shift Del (DEL) | VAF 63/448 reads (14%) | called by mutect2, pindel, varscan2
- ARMCX2 | c.773A>G p.K258R | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP7B | c.1930_1931del p.K644Dfs*110 | Frame Shift Del (DEL) | VAF 58/236 reads (25%) | called by mutect2, pindel, varscan2
- AVIL | c.1956G>A p.W652* | Nonsense Mutation (SNP) | VAF 1760/1881 reads (94%) | called by muse, mutect2, varscan2
- BICD2 | c.2270A>G p.Y757C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BSN | c.2627_2640del p.K876Tfs*4 | Frame Shift Del (DEL) | VAF 21/130 reads (16%) | called by mutect2, pindel, varscan2
- C12orf40 | c.1505dup p.D502Efs*2 | Frame Shift Ins (INS) | VAF 23/199 reads (12%) | called by mutect2, pindel, varscan2
- CCN1 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 102/511 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- CDH2 | c.2026T>C p.Y676H | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- CDT1 | c.1333del p.E445Sfs*7 | Frame Shift Del (DEL) | VAF 60/242 reads (25%) | called by mutect2, pindel, varscan2
- CRADD | c.440_452del p.R147Pfs*62 | Frame Shift Del (DEL) | VAF 44/356 reads (12%) | called by mutect2, pindel
- DDX11 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 244/4024 reads (6%) | called by muse, mutect2
- DIDO1 | c.3287G>A p.R1096K | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EFCAB3 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- F12 | c.1561_1566del p.E521_A522del | In Frame Del (DEL) | VAF 98/476 reads (21%) | called by mutect2, pindel, varscan2
- FAM124A | c.538del p.Y180Tfs*13 (on ENST00000322475 / NM_001242312.2; = p.Y216Tfs*13 on NM_145019.4) | Frame Shift Del (DEL) | VAF 62/221 reads (28%) | called by mutect2, pindel, varscan2
- FASLG | c.567C>A p.Y189* | Nonsense Mutation (SNP) | VAF 59/372 reads (16%) | called by muse, mutect2, varscan2
- FBXO7 | c.128A>G p.N43S | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCRTR2 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HPD | c.1155G>C p.E385D | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HTATSF1 | c.1510A>C p.K504Q | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITPR1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 95/583 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNN3 | c.1919C>G p.A640G (on ENST00000618040 / NM_001204087.1; = p.A625G on NM_002249.6) | Missense Mutation (SNP) | VAF 76/468 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- KDM6B | c.2225C>G p.P742R | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, varscan2
- KIAA2026 | c.296_297insA p.F101Lfs*111 | Frame Shift Ins (INS) | VAF 16/94 reads (17%) | called by mutect2, varscan2
- LCE2C | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 119/295 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LONP1 | c.2555A>G p.D852G | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPA | c.2883C>G p.C961W | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRRC3 | c.197C>G p.T66S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MGST3 | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NKTR | c.2651A>C p.K884T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- NLRC5 | c.2191A>G p.I731V | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NMS | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.026); called by muse, mutect2
- PGM2 | c.454T>G p.S152A | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHF3 | c.725del p.N242Ifs*5 | Frame Shift Del (DEL) | VAF 15/114 reads (13%) | called by mutect2, pindel, varscan2
- PIR | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- RBP3 | c.1784T>C p.V595A | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- RNF113A | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SEC31B | c.1525_1526del p.P510Sfs*6 | Frame Shift Del (DEL) | VAF 40/174 reads (23%) | called by pindel, varscan2
- SPZ1 | c.930_935delinsT p.S311* | Frame Shift Del (DEL) | VAF 31/116 reads (27%) | called by pindel, varscan2*
- STARD9 | c.9215A>G p.H3072R | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- SWT1 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2
- TENM1 | c.1357A>G p.T453A | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- TENM3 | c.7094C>A p.T2365K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TM6SF2 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.038); called by muse, mutect2
- TMEM135 | c.443C>G p.T148R | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM55 | c.963A>G p.I321M | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TRPM5 | c.1660A>G p.I554V | Missense Mutation (SNP) | VAF 108/167 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TSPAN8 | c.445-2A>G p.X149_splice | Splice Site (SNP) | VAF 57/343 reads (17%) | called by muse, mutect2, varscan2
- URB2 | c.1543T>C p.S515P | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- XCL2 | c.290C>A p.T97N | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ZNF711 | c.35C>A p.T12K | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ADRB3 | c.312G>A p.P104= | Silent (SNP) | VAF 54/243 reads (22%) | called by muse, mutect2, varscan2
- AHNAK2 | c.13956C>A p.I4652= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs771880486, COSV60910825; called by muse, mutect2, varscan2
- CCDC85B | c.282C>T p.A94= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as rs1438800562; called by muse, mutect2
- COL21A1 | c.780A>C p.T260= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- COL26A1 | c.222G>A p.T74= | Silent (SNP) | VAF 50/246 reads (20%) | catalogued as rs373555150; called by muse, mutect2, varscan2
- DENND1A | c.3012G>A p.Q1004= | Silent (SNP) | VAF 59/213 reads (28%) | called by muse, mutect2, varscan2
- EVC | c.1602C>T p.F534= | Silent (SNP) | VAF 112/562 reads (20%) | catalogued as rs766294209, COSV53831002; called by muse, mutect2, varscan2
- F2RL3 | c.864G>T p.V288= | Silent (SNP) | VAF 32/141 reads (23%) | called by muse, mutect2, varscan2
- FLG | c.3627G>A p.G1209= | Silent (SNP) | VAF 100/614 reads (16%) | called by muse, mutect2, varscan2
- GK3P | c.873T>C p.H291= | Silent (SNP) | VAF 76/300 reads (25%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.624C>T p.D208= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as rs369654526; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.126A>G p.P42= | Silent (SNP) | VAF 34/246 reads (14%) | catalogued as rs1335010944; called by muse, mutect2, varscan2
- ITGAX | c.1107T>G p.A369= | Silent (SNP) | VAF 38/236 reads (16%) | called by muse, mutect2, varscan2
- MS4A14 | c.1212T>C p.D404= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs1418776584; called by muse, mutect2, varscan2
- PUM2 | c.2256T>A p.T752= | Silent (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- RPAP1 | c.141G>A p.R47= | Silent (SNP) | VAF 51/117 reads (44%) | called by muse, mutect2, varscan2
- SLC17A7 | c.483C>A p.I161= | Silent (SNP) | VAF 50/315 reads (16%) | called by muse, mutect2, varscan2
- SLC39A6 | c.1515T>C p.D505= | Silent (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- SPAG7 | c.522A>G p.G174= | Silent (SNP) | VAF 34/410 reads (8%) | called by muse, mutect2
- SYNPO2 | c.3444A>G p.Q1148= | Silent (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- SYT16 | c.432G>A p.E144= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs1482341816, COSV70857532; called by muse, mutect2, varscan2
- TAS2R14 | c.462C>A p.A154= | Silent (SNP) | VAF 911/1078 reads (85%) | called by muse, mutect2, varscan2
- TNFSF14 | c.372G>A p.R124= | Silent (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2
- TSNAXIP1 | c.192G>T p.L64= | Silent (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- UBR2 | c.2328T>C p.D776= | Silent (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- ZBTB26 | c.417T>C p.C139= | Silent (SNP) | VAF 49/126 reads (39%) | called by muse, mutect2, varscan2
- ZIM3 | c.468C>T p.G156= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as rs758265716; called by muse, mutect2, varscan2
- ZNF335 | c.1944C>T p.P648= | Silent (SNP) | VAF 28/354 reads (8%) | catalogued as COSV100532787; called by muse, mutect2
- ZNF469 | c.9675A>G p.G3225= (on ENST00000437464; = p.G3253= on NM_001367624.2) | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- AC005008.2 | n.16T>C | RNA (SNP) | VAF 37/143 reads (26%) | called by muse, mutect2, varscan2
- AC098591.2 | n.1050C>T | RNA (SNP) | VAF 53/299 reads (18%) | catalogued as rs761360875; called by muse, mutect2, varscan2
- B4GALT7 | c.-32del | 5'UTR (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- CASK | c.278+35T>G | Intron (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- CCBE1 | c.554-83G>A | Intron (SNP) | VAF 102/255 reads (40%) | called by muse, mutect2, varscan2
- CCDC78 | c.60+73_60+84del | Intron (DEL) | VAF 51/339 reads (15%) | called by mutect2, pindel, varscan2
- DYNC2I1 | c.1358-843T>C | Intron (SNP) | VAF 8/38 reads (21%) | catalogued as rs934500344; called by muse, varscan2
- EML3 | c.1915-16T>A | Intron (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- GDF5 | c.-43C>T | 5'UTR (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2
- H3-2 | c.*344T>C | 3'UTR (SNP) | VAF 69/295 reads (23%) | called by muse, mutect2, varscan2
- HERC2P2 | n.2943A>G | RNA (SNP) | VAF 64/199 reads (32%) | called by muse, mutect2, varscan2
- IGHD1-1 | chr14:105922285 G>T | 5'Flank (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- MT3 | c.-26C>T | 5'UTR (SNP) | VAF 8/15 reads (53%) | called by mutect2, varscan2
- OR7D1P | n.821C>T | RNA (SNP) | VAF 26/140 reads (19%) | called by muse, mutect2, varscan2
- PBDC1 | chrX:76173051 A>G | 5'Flank (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2, varscan2
- PHEX | c.1966-16C>G | Intron (SNP) | VAF 35/201 reads (17%) | called by muse, mutect2, varscan2
- PKD1L2 | n.730C>T | RNA (SNP) | VAF 8/42 reads (19%) | catalogued as rs368352203; called by muse, varscan2
- SLC6A8 | c.777+350G>T | Intron (SNP) | VAF 41/230 reads (18%) | called by muse, mutect2, varscan2
- TUBA1B | c.-38C>G | 5'UTR (SNP) | VAF 42/244 reads (17%) | called by muse, mutect2, varscan2
